Gene-level copy-number profile of tumor specimen TCGA-RC-A6M3-01A from TCGA case TCGA-RC-A6M3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 24.4 years (8,899 days).
Specimen TCGA-RC-A6M3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.aa3dbac0-cd24-4a4a-affa-d6e4faebc90e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RC-A6M3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8edc685-105e-4853-a93b-478c486a71ba

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 295; copy number 2: 568; copy number 3: 15,250; copy number 4: 22,095; copy number 5: 4,642; copy number 6: 14,499; copy number 7: 1,047; copy number 8: 677; copy number 9: 432; copy number 10: 6; copy number 11: 195; copy number 13: 73; copy number 14: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RC-A6M3-01A-11D-A32F-01): tumor purity 0.54, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 743 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:198,493,242–199,476,935, 7 genes, copy number 9 (within-gene range 5–9): AC019330.1, AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1, SATB2-AS1.
- chr2:199,955,317–201,176,687, 39 genes, copy number 9–14 (within-gene range 4–14): MAIP1, AC004464.1, SPATS2L, RNY4P34, AC012459.1, KCTD18, SGO2, AOX1, AOX3P, AOX3P-AOX2P, LINC01792, AOX2P, RNU1-133P, BZW1-AS1, BZW1, RNU6-31P, BICD1P1, RNA5SP115, CLK1, Y_RNA, PPIL3, RNU6-312P, NIF3L1, RNU6-762P, ORC2, AC005037.1, FAM126B, HNRNPA1P35, RPL23AP30, NDUFB3, RNU6-1206P, Metazoa_SRP, AC007272.1, RPL17P10, CFLAR, IMPDH1P10, CFLAR-AS1, RNU7-45P, RPL38P5.
- chr2:228,169,743–228,841,689, 6 genes, copy number 10: RNU6-624P, SNF8P1, AC009410.1, LINC01807, AC012070.1, RPL7L1P10.
- chr8:60,965,802–75,566,834, 231 genes, copy number 9 (broad region; genes not listed).
- chr8:78,148,101–91,219,236, 195 genes, copy number 11 (broad region; genes not listed).
- chr8:92,668,660–95,811,254, 73 genes, copy number 13 (within-gene range 5–13) (broad region; genes not listed).
- chr21:38,733,890–39,515,506, 33 genes, copy number 9 (within-gene range 8–9): LINC00114, ETS2, AP001042.1, AP001042.2, AP001042.3, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.3, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1, BRWD1, AF129408.1, TIMM9P2, BRWD1-IT1, METTL21AP1, BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA, RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4.
- chr21:41,007,244–45,226,560, 159 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 295. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
